Gene-level copy-number profile of tumor specimen ALCH-AELA-TTP1-A from ALCHEMIST case ALCH-AELA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 77.1 years (28,179 days).
Specimen ALCH-AELA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7f1c536a-7631-4f70-a0f8-aba233f6db6c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AELA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/acc7bae8-4892-438d-a95a-4895309b66cc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 531; copy number 1: 60; copy number 2: 21,964; copy number 3: 2,731; copy number 4: 28,569; copy number 5: 1,044; copy number 6: 2,945; copy number 7: 520; copy number 8: 38; copy number 9: 37; copy number 10: 74; copy number 11: 345; copy number 12: 57.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes (within-gene range 0–4): Y_RNA, RNU6-904P, RPS16P3.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:3,373,353–3,375,226, 1 gene (within-gene range 0–2): AC026991.1.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–2): RNA5SP251.
- chr8:7,190,901–7,200,857, 2 genes: RPS3AP33, AF228730.1.
- chr8:12,150,895–12,151,134, 1 gene (within-gene range 0–2): DEFB109D.
- chr9:452,492–492,248, 1 gene (within-gene range 0–3): AL161725.1.
- chr9:477,750–495,610, 2 genes (within-gene range 0–3): RPL12P25, AL161725.2.
- chr9:28,598,668–28,599,292, 1 gene (within-gene range 0–3): KCTD10P1.
- chr14:23,619,201–23,645,639, 2 genes: AL135999.3, DHRS2.
- chr16:90,173,217–90,222,851, 1 gene (within-gene range 0–2): LINC02193.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 513 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:144,186,905–147,370,656, 24 genes, copy number 9: RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1, LINC02010, RNU6-505P, RPL21P71.
- chr3:174,377,244–175,810,548, 3 genes, copy number 11 (within-gene range 8–11): AC069218.1, NAALADL2, RN7SKP40.
- chr3:175,369,540–198,123,232, 480 genes, copy number 9–12 (broad region; genes not listed).
- chr11:34,533,014–34,916,379, 6 genes, copy number 9 (within-gene range 6–9): AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP.

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
